Surgical pathology report (de-identified scan), TCGA case TCGA-BB-4217, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-4217-01A (Primary Tumor).

[page 1 of 2]
LAB RESULTS

RG PATH REPORT

LECTION DATE/TIME:

1st Specimen collected on

Accessioned on

FINAL DIAGNOSIS ----- Pathologist:

1) LEFT TONGUE BASE (EXCISION): SQUAMOUS MUCOSA. NEGATIVE FOR TUMOR.

2) RIGHT POSTERIOR PHARYNGEAL WALL (EXCISION): SQUAMOUS MUCOSA. NEGATIVE FOR TUMOR.

3) NASOPHARYNGEAL MARGIN (EXCISION): SQUAMOUS MUCOSA. NEGATIVE FOR TUMOR.

4) SOFT PALATE UVULA (EXCISION): ULCERATED SQUAMOUS MUCOSA WITH FOCAL HIGH GRADE DYSPLASIA. SEE NOTE.

NOTE: The focal high grade dysplasia is seen only on the frozen section.

5) 2ND NASOPHARYNGEAL MARGIN (EXCISION): SQUAMOUS MUCOSA WITH CHRONIC INFLAMMATION. NEGATIVE FOR TUMOR.

6) LEFT EUSTACHIAN TUBE (EXCISION): SQUAMOUS MUCOSA. NEGATIVE FOR TUMOR.

7) 2ND SOFT PALATE (EXCISION): SQUAMOUS MUCOSA. NEGATIVE FOR TUMOR.

8) TUMOR AT NASOPHARYNX (EXCISION): INFILTRATING POORLY DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA.

ADDITIONAL NASOPHARYNX (EXCISION): RESPIRATORY MUCOSA WITH CHRONIC INFLAMMATION. NEGATIVE FOR TUMOR.

10) SOFT TISSUE RIGHT LINGUAL ARTERY (EXCISION): BENIGN FIBROCONNECTIVE TISSUE. NEGATIVE FOR TUMOR.

11) ADDITIONAL SOFT PALATE (EXCISION): SQUAMOUS MUCOSA AND MINOR SALIVARY GLAND. NEGATIVE FOR TUMOR.

12) LYMPH NODES, RIGHT NECK (DISSECTION): TWO OF ELEVEN (2/11) LYMPH NODES POSITIVE FOR SQUAMOUS CELL CARCINOMA. ONE NODE SHOWS EXTRACAPSULAR EXTENSION.

13) LYMPH NODES, RIGHT NECK LEVEL IV (DISSECTION): ONE OF EIGHT (1/8) LYMPH NODES POSITIVE FOR SQUAMOUS CELL CARCINOMA. EXTRACAPSULAR EXTENSION IS PRESENT.

14) LYMPH NODES, LEFT NECK (DISSECTION): THREE (3) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

15) LYMPH NODES, LEVELS II AND III (DISSECTION): ONE OF SEVEN (1/7) LYMPH NODES POSITIVE FOR SQUAMOUS CELL CARCINOMA WITH EXTENSION INTO SOFT TISSUE FORMING A NODULE OF SQUAMOUS CELL CARCINOMA. (5.0 CM)..

16) LYMPH NODES, LEFT NECK LEVEL IV (DISSECTION): TWO OF SEVENTEEN (2/17) LYMPH NODES POSITIVE FOR SQUAMOUS CELL CARCINOMA.

17) LARYNX (LARYNGOPHARYNGECTOMY):

SPECIMEN:

Laryngopharyngectomy

TUMOR SITE:

Posterior pharyngeal space

TCGA-BB-4217

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

[page 2 of 2]
[REDACTED]

STOLOGIC TYPE:
Squamous cell carcinoma (keratinizing)

TUMOR SIZE:
9 cm greatest dimension

HISTOLOGIC GRADE:
[REDACTED] Poorly differentiated

LYMPH NODES:
Metastatic carcinoma in 6 of 51 lymph nodes: Ipsilateral,
Contralateral
Specify largest positive node: 5 cm

EXTRANODAL EXTENSION:
Present

EXTENT OF INVASION
PRIMARY TUMOR:
pT4: Tumor invades nasopharynx (see part 8)

REGIONAL LYMPH NODES:
pN2c: Metastasis in bilateral or contralateral lymph nodes, none
larger than 6 cm in greatest dimension

DISTANT METASTASIS:
pMx: Cannot be assessed

MARGINS:
Margins are uninvolved
Distance of invasive carcinoma from nearest margin: 1 mm
Specify margin: Soft tissue

VENOUS/LYMPHATIC INVASION:
Present

PERINEURAL INVASION:
Present

NOTE: This case was reviewed with [REDACTED] who concurs with the
diagnosis.

Reported by:
[REDACTED]

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:
[REDACTED]

Source: NCI Genomic Data Commons file 5b2a8ae1-bb30-46a2-bb42-35896cc05732 (TCGA-BB-4217.002080FA-FBDE-47C1-940E-6086C14DE03B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).